Somatic mutation profile of tumor specimen TCGA-13-0897-01A (aliquot TCGA-13-0897-01A-01W-0421-09) from TCGA case TCGA-13-0897, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.5 years (19,894 days).
Specimen TCGA-13-0897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f2db0a-529c-4ca2-8e06-771ec4369508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0897-10A (Blood Derived Normal), aliquot TCGA-13-0897-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac5db728-467b-4599-bed9-018d3d016235

The open-access MAF lists 53 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD6 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV55909404; called by muse, mutect2, varscan2
- ADGRV1 | c.1722C>G p.I574M | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67990057; called by muse, mutect2, varscan2
- ASH2L | c.290C>G p.T97S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV51700363; called by muse, mutect2, varscan2
- BAG3 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.599); catalogued as rs1454148171, COSV64842287; called by muse, mutect2, varscan2
- BRD4 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54590016; called by muse, mutect2, varscan2
- CAMSAP1 | c.3204A>C p.K1068N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV100409563; called by muse, mutect2, varscan2
- COL16A1 | c.2610+1G>A p.X870_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | catalogued as COSV54710375; called by muse, mutect2, varscan2
- DTX3L | c.1156A>C p.K386Q | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as COSV56144960; called by muse, mutect2, varscan2
- FAM135B | c.2674A>G p.R892G | Missense Mutation (SNP) | VAF 85/649 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52739054; called by muse, mutect2, varscan2
- FGD6 | c.4170G>C p.E1390D | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV59692623; called by muse, mutect2, varscan2
- GABRA1 | c.856+2T>A p.X286_splice | Splice Site (SNP) | VAF 128/217 reads (59%) | catalogued as COSV50111096; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 206/516 reads (40%) | catalogued as rs746342179; called by muse, mutect2, varscan2
- ITK | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as COSV70060980, COSV70063711; called by muse, mutect2, varscan2
- KIF15 | c.2706G>C p.L902F | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58162853; called by muse, mutect2, varscan2
- MAGEH1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61678912; called by muse, mutect2, varscan2
- MFAP3L | c.79_102delinsTAACTA p.T27_S34delins* | Nonsense Mutation (DEL) | VAF 42/190 reads (22%) | catalogued as COSV64372502; called by pindel, varscan2*
- MYH11 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100257669; called by muse, mutect2, varscan2
- MYH14 | c.5430G>T p.Q1810H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV51824234, COSV51824621; called by muse, mutect2, varscan2
- NCOA6 | c.5408C>A p.S1803Y | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV62865650; called by muse, mutect2, varscan2
- NDUFS1 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51911494; called by muse, mutect2, varscan2
- NISCH | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs745490517, COSV61900384; called by muse, mutect2, varscan2
- NLGN3 | c.1506C>G p.Y502* (on ENST00000358741 / NM_181303.2; = p.Y482* on NM_018977.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as COSV62444415; called by muse, mutect2, varscan2
- NOX4 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV54458138, COSV54458661; called by muse, mutect2
- NT5DC3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368049739, COSV101231049; called by muse, mutect2, varscan2
- ODAM | c.460T>G p.W154G | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV68572520, COSV68573154; called by muse, mutect2, varscan2
- OR2L8 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs572027464, COSV61727514, COSV61727605; called by muse, mutect2, varscan2
- OR5AS1 | c.794G>C p.S265T | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV100546228, COSV57982454; called by muse, mutect2, varscan2
- PALD1 | c.575T>A p.L192H | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54976258, COSV99698372; called by muse, varscan2
- RNF130 | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV56151823; called by muse, mutect2, varscan2
- RNF169 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV55133996; called by muse, mutect2, varscan2
- RPL32 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 45/137 reads (33%) | catalogued as COSV55992051; called by muse, mutect2, varscan2
- RSPO2 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 209/593 reads (35%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV52649372; called by muse, mutect2, varscan2
- SLC17A6 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV54138711, COSV54141154; called by muse, mutect2, varscan2
- SLC18B1 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 97/156 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51595357; called by muse, mutect2, varscan2
- SLCO5A1 | c.1031T>C p.I344T | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs750358609, COSV52663435; called by muse, mutect2, varscan2
- SLIT3 | c.1138T>A p.S380T | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV60621090; called by muse, mutect2, varscan2
- TAS2R43 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 186/293 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67858931; called by muse, varscan2
- TP53 | c.848_849insT p.T284Hfs*22 | Frame Shift Ins (INS) | VAF 45/76 reads (59%) | catalogued as COSV99367543; called by mutect2, pindel, varscan2
- ZNF770 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV62544598; called by muse, mutect2, varscan2
- CIC | c.3020_3032del p.V1007Afs*28 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- MCF2L2 | c.2391_2400del p.K797Nfs*12 | Frame Shift Del (DEL) | VAF 257/701 reads (37%) | called by mutect2, pindel, varscan2
- MGA | c.6882del p.D2295Tfs*40 (on ENST00000219905 / NM_001164273.1; = p.D2086Tfs*40 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 41/78 reads (53%) | called by mutect2, pindel, varscan2
- OR5AP2 | c.326_352del p.F109_E117del | In Frame Del (DEL) | VAF 42/168 reads (25%) | called by mutect2, pindel, varscan2
- ATRIP | c.1560A>G p.G520= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56497516; called by muse, mutect2, varscan2
- CHSY3 | c.1506G>A p.V502= | Silent (SNP) | VAF 5/104 reads (5%) | catalogued as COSV100518478; called by muse, mutect2
- CYP2F1 | c.666C>T p.S222= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs1377639448, COSV58528248; called by muse, mutect2, varscan2
- FAF1 | c.1668C>G p.S556= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as COSV65641096, COSV65642998; called by muse, mutect2, varscan2
- KIRREL2 | c.705A>G p.P235= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV52878242; called by muse, mutect2, varscan2
- OR5B2 | c.690G>A p.K230= | Silent (SNP) | VAF 95/256 reads (37%) | catalogued as COSV56909027; called by muse, mutect2, varscan2
- PGM1 | c.1008C>T p.P336= | Silent (SNP) | VAF 71/154 reads (46%) | catalogued as rs930181526, COSV64301000; called by muse, mutect2, varscan2
- PPP1R15B | c.198G>T p.L66= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs773326374, COSV65816119; called by muse, mutect2, varscan2
- RNF144A | c.13A>C p.R5= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV57983819; called by muse, mutect2, varscan2
- SLC27A3 | c.1629C>A p.R543= (on ENST00000271857; = p.R415= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV55164665; called by muse, mutect2, varscan2
